Somatic mutation profile of tumor specimen C3N-03453-01 (aliquot CPT0225990006) from CPTAC case C3N-03453, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.9 years (19,695 days).
Specimen C3N-03453-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b82bd64-08ec-4ccd-b1c0-2ca63a45554b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03453-31 (Blood Derived Normal), aliquot CPT0226010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63039318-f955-44f7-8afd-48949d2ffcb0

The open-access MAF lists 108 somatic variants for this specimen: 72 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 28, Intron 4, Nonsense Mutation 4, Splice Site 3, 3'UTR 2, Frame Shift Ins 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 1918/6972 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 209/610 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as rs137853243, CM004772, COSV57465455; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH2 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 134/405 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs147708782, CM145482; ClinVar: pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.2359G>A p.A787T | Missense Mutation (SNP) | VAF 167/478 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs142988897, CM068052; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.802-1G>A p.X268_splice | Splice Site (SNP) | VAF 59/87 reads (68%) | hotspot (GDC flag); catalogued as rs1257124719, COSV100909782, COSV64290925, COSV64293353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRE5 | c.1154G>T p.W385L (on ENST00000242786 / NM_078481.4; = p.W292L on NM_001784.5) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as COSV99662953; called by muse, mutect2, varscan2
- AGAP2 | c.1513C>T p.R505* (on ENST00000547588 / NM_001122772.2; = p.R169* on NM_014770.4) | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | catalogued as rs1485087775, COSV57726893; called by muse, mutect2, varscan2
- ALPI | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 173/444 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55013363; called by muse, mutect2, varscan2
- ANKRD30B | c.3467C>T p.T1156M | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs779304044, COSV57704544; called by muse, mutect2, varscan2
- CD207 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 188/491 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs372230506; called by muse, mutect2, varscan2
- COL6A6 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 100/275 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs371129727; called by muse, mutect2, varscan2
- CYP2F1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 75/377 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1198261726, COSV58527442; called by muse, mutect2, varscan2
- DNAH12 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs534723794; called by muse, varscan2
- DNAH6 | c.4639G>A p.A1547T | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1021058433, COSV52858792; called by muse, mutect2, varscan2
- EPHB6 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 180/707 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.083); catalogued as rs761901290; called by muse, mutect2, varscan2
- ERCC2 | c.902C>T p.T301M | Missense Mutation (SNP) | VAF 80/355 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.309); catalogued as rs199863965, COSV55543175; called by muse, mutect2, varscan2
- ETV5 | c.232+1G>A p.X78_splice | Splice Site (SNP) | VAF 12/94 reads (13%) | catalogued as COSV60502537; called by muse, mutect2, varscan2
- GCKR | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 72/208 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs150882877; called by muse, mutect2, varscan2
- GJA8 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 94/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99569259; called by muse, mutect2, varscan2
- HAVCR1 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as rs150731397; called by muse, mutect2, varscan2
- IGHV4-59 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 167/664 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs782709857; called by muse, mutect2, varscan2
- KLRF2 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs761206884, COSV73374353; called by muse, mutect2, varscan2
- LRRC32 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 196/545 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs1421225242; called by muse, mutect2
- MGAM2 | c.2629G>A p.V877I | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs756992949; called by muse, mutect2, varscan2
- MUC5AC | c.15877G>A p.G5293S | Missense Mutation (SNP) | VAF 127/412 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.048); catalogued as rs1368288476; called by muse, mutect2, varscan2
- MYRF | c.2383G>A p.E795K (on ENST00000278836 / NM_001127392.3; = p.E786K on NM_013279.4) | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.4); catalogued as rs747754768; called by muse, mutect2, varscan2
- NAALAD2 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs749818857, COSV58961384; called by muse, mutect2, varscan2
- PGF | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs774071153, COSV53124744; called by muse, mutect2, varscan2
- PKP2 | c.1811C>T p.T604M | Missense Mutation (SNP) | VAF 99/291 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs373360192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SAMSN1 | c.129+1G>T p.X43_splice | Splice Site (SNP) | VAF 19/57 reads (33%) | catalogued as rs1454906853; called by muse, varscan2
- SGO2 | c.2717T>C p.L906P | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1559218243; called by muse, mutect2, varscan2
- SLC6A3 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 160/255 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as rs920989049, COSV54363099, COSV99547896; called by muse, mutect2, varscan2
- SNAP91 | c.2614G>A p.A872T | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.615); catalogued as rs1194743928; called by muse, mutect2, varscan2
- ST8SIA2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 156/372 reads (42%) | PolyPhen benign (0.015); catalogued as rs370891354, COSV51572264; called by muse, mutect2, varscan2
- TNS3 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200656291; called by muse, mutect2, varscan2
- TUBGCP5 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.93); catalogued as rs1295994236; called by muse, mutect2, varscan2
- ZG16 | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1326568902; called by muse, mutect2, varscan2
- ZNF556 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 140/500 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768949953, COSV56911664; called by muse, mutect2, varscan2
- ACSM5 | c.1556T>A p.V519D | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- AL592490.1 | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C6 | c.2754A>T p.R918S | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CD180 | c.1045C>A p.H349N | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); called by muse, mutect2
- CD19 | c.519T>A p.C173* | Nonsense Mutation (SNP) | VAF 64/441 reads (15%) | called by muse, mutect2, varscan2
- CELSR3 | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 198/540 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CHRM2 | c.880T>C p.S294P | Missense Mutation (SNP) | VAF 87/293 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- COL5A3 | c.2867G>A p.G956E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDI1 | c.627A>C p.E209D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- DNAH3 | c.6488G>A p.W2163* | Nonsense Mutation (SNP) | VAF 86/236 reads (36%) | called by muse, mutect2, varscan2
- FSIP2 | c.1733C>G p.T578R | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRM3 | c.791T>A p.L264* | Nonsense Mutation (SNP) | VAF 117/453 reads (26%) | called by muse, mutect2, varscan2
- KRTAP12-2 | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 258/765 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LSMEM1 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- METTL6 | c.115C>G p.Q39E | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAP1 | c.1879A>T p.I627L | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4Q2 | c.559C>A p.L187I | Missense Mutation (SNP) | VAF 123/323 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5L2 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- OR8J3 | c.568T>C p.S190P | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PEAR1 | c.1160C>A p.A387E | Missense Mutation (SNP) | VAF 77/212 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHC1 | c.1430T>G p.L477R | Missense Mutation (SNP) | VAF 100/489 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- PLCH2 | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 143/420 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PNPLA6 | c.1280G>A p.G427D (on ENST00000414982 / NM_001166111.2; = p.G379D on NM_006702.5) | Missense Mutation (SNP) | VAF 112/549 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKCE | c.1045A>T p.T349S | Missense Mutation (SNP) | VAF 113/303 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PTPRZ1 | c.419dup p.E141Rfs*3 | Frame Shift Ins (INS) | VAF 41/187 reads (22%) | called by mutect2, pindel, varscan2
- RPL5 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- SLC22A14 | c.404T>A p.L135H | Missense Mutation (SNP) | VAF 139/334 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- TAF1L | c.3814A>G p.K1272E | Missense Mutation (SNP) | VAF 133/333 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- TAT | c.132G>T p.R44S | Missense Mutation (SNP) | VAF 247/727 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TGM2 | c.1459A>G p.S487G | Missense Mutation (SNP) | VAF 209/640 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- TRIM36 | c.1940A>T p.K647M | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- TRPV5 | c.43C>A p.L15I | Missense Mutation (SNP) | VAF 33/314 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- VWA7 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 147/380 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- ZNF257 | c.1151C>G p.S384C | Missense Mutation (SNP) | VAF 70/316 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCG5 | c.762T>C p.S254= | Silent (SNP) | VAF 158/442 reads (36%) | called by muse, mutect2, varscan2
- AGO2 | c.39G>A p.A13= | Silent (SNP) | VAF 60/144 reads (42%) | catalogued as rs1053018290; called by muse, mutect2, varscan2
- CD48 | c.24G>T p.S8= | Silent (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2, varscan2
- CFAP92 | c.2175G>A p.L725= | Silent (SNP) | VAF 33/349 reads (9%) | called by muse, mutect2
- CHST5 | c.249C>T p.S83= | Silent (SNP) | VAF 59/432 reads (14%) | catalogued as rs941427325; called by muse, mutect2, varscan2
- COL12A1 | c.2656T>C p.L886= | Silent (SNP) | VAF 41/273 reads (15%) | called by muse, mutect2, varscan2
- CRYBG1 | c.3093G>A p.P1031= | Silent (SNP) | VAF 115/315 reads (37%) | catalogued as rs150468985; called by muse, mutect2, varscan2
- CUBN | c.8979C>T p.T2993= | Silent (SNP) | VAF 89/425 reads (21%) | called by muse, mutect2, varscan2
- CUL9 | c.972C>T p.S324= | Silent (SNP) | VAF 69/148 reads (47%) | catalogued as rs140962096; called by muse, mutect2, varscan2
- EARS2 | c.390G>A p.A130= | Silent (SNP) | VAF 74/232 reads (32%) | catalogued as rs754020113, COSV71942933; called by muse, mutect2, varscan2
- EBF3 | c.1209G>A p.K403= (on ENST00000355311 / NM_001375392.1; = p.K394= on NM_001005463.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as rs1338646144; called by muse, mutect2
- ERVV-1 | c.786A>G p.K262= | Silent (SNP) | VAF 150/484 reads (31%) | called by muse, mutect2, varscan2
- FAT2 | c.9771C>T p.S3257= | Silent (SNP) | VAF 182/535 reads (34%) | catalogued as COSV55817540, COSV99943638; called by muse, mutect2, varscan2
- HECW2 | c.3525G>A p.S1175= | Silent (SNP) | VAF 51/136 reads (38%) | catalogued as rs771364114, COSV53668005; called by muse, mutect2, varscan2
- HOXA2 | c.1026C>T p.P342= | Silent (SNP) | VAF 174/748 reads (23%) | called by muse, mutect2, varscan2
- ITIH6 | c.3855G>T p.L1285= | Silent (SNP) | VAF 123/219 reads (56%) | called by muse, mutect2, varscan2
- MPC1L | c.276G>A p.A92= | Silent (SNP) | VAF 128/198 reads (65%) | called by muse, mutect2, varscan2
- NCR3 | c.297A>G p.R99= | Silent (SNP) | VAF 55/357 reads (15%) | called by muse, mutect2, varscan2
- OR13C8 | c.309T>C p.I103= | Silent (SNP) | VAF 86/287 reads (30%) | called by muse, mutect2, varscan2
- RAB37 | c.165G>C p.L55= | Silent (SNP) | VAF 82/302 reads (27%) | called by muse, mutect2, varscan2
- RIMS2 | c.3189G>A p.S1063= (on ENST00000666250 / NM_001348490.2; = p.S871= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 83/245 reads (34%) | catalogued as rs746828846, COSV51709477; called by muse, mutect2, varscan2
- SCNN1A | c.822G>A p.T274= | Silent (SNP) | VAF 46/395 reads (12%) | catalogued as rs372634287; called by muse, mutect2, varscan2
- SKOR2 | c.2184C>T p.S728= | Silent (SNP) | VAF 61/136 reads (45%) | catalogued as rs1413625623; called by muse, mutect2, varscan2
- SPHKAP | c.3864T>A p.S1288= | Silent (SNP) | VAF 49/152 reads (32%) | called by muse, mutect2, varscan2
- TTLL8 | c.468C>T p.N156= | Silent (SNP) | VAF 98/316 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.2514T>A p.A838= (on ENST00000591111; = p.A792= on NM_003319.4) | Silent (SNP) | VAF 91/236 reads (39%) | catalogued as rs766236539; called by muse, mutect2, varscan2
- UGT2B7 | c.1518T>C p.F506= | Silent (SNP) | VAF 148/378 reads (39%) | catalogued as rs1295265690; called by muse, mutect2, varscan2
- ZNF735 | c.393A>G p.R131= | Silent (SNP) | VAF 87/318 reads (27%) | catalogued as rs1475281528; called by muse, mutect2, varscan2
- C12orf75 | c.*73G>A | 3'UTR (SNP) | VAF 106/310 reads (34%) | catalogued as rs1200436774; called by muse, mutect2, varscan2
- GALNT9 | c.1077+7224A>T | Intron (SNP) | VAF 134/359 reads (37%) | called by muse, mutect2, varscan2
- HAPLN1 | c.-26-17_-26-14del | Intron (DEL) | VAF 40/133 reads (30%) | called by mutect2, pindel, varscan2
- NPIPB14P | chr16:69976689 G>C | 3'Flank (SNP) | VAF 40/839 reads (5%) | called by muse, mutect2
- NPIPB1P | n.762C>G | RNA (SNP) | VAF 34/401 reads (8%) | called by muse, varscan2
- OPRM1 | c.1165-11071T>A | Intron (SNP) | VAF 85/255 reads (33%) | called by muse, mutect2, varscan2
- PON2 | c.*47T>C | 3'UTR (SNP) | VAF 11/94 reads (12%) | catalogued as rs1279221005; called by muse, mutect2, varscan2
- SPOPL | c.1034+14A>G | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
